Gene-level copy-number profile of tumor specimen HTMCP-02-01-01252-01A from CGCI case HTMCP-02-01-01252, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male; Vital status: Dead; Primary diagnosis: Lepidic predominant adenocarcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage III.
Specimen HTMCP-02-01-01252-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0caa96d9-ecc5-47ae-ad54-d62f7b660127.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-01-01252-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,732 have no estimate.
https://portal.gdc.cancer.gov/files/086a2423-37c4-40f1-9687-3ce9f570ddef

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,603; copy number 2: 53,987; copy number 3: 1,289; copy number 4: 7; copy number 5: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:32,439,069–32,441,159, 1 gene, copy number 5: PABPC1P13.
- chr16:33,769,421–33,771,248, 2 genes, copy number 5: ENPP7P13, AC136428.2.
- chr16:33,857,935–33,859,352, 2 genes, copy number 5: AC140658.2, IGHV3OR16-11.

Autosomal genes at a single copy (total copy number 1): 747. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
